Somatic mutation profile of tumor specimen MP2PRT-PAUWMN-TBP1-A (aliquot MP2PRT-PAUWMN-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAUWMN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,278 days).
Specimen MP2PRT-PAUWMN-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fb16933-9abc-4e54-bcd6-3d94f64298cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUWMN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUWMN-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67c1412e-4524-471c-8b8d-4cea844b4ef0

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSCAM | c.3659G>A p.R1220Q | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs755579756, COSV68020290; called by muse, mutect2, varscan2
- GRIP2 | c.1141G>A p.V381M (on ENST00000619221; = p.V284M on NM_001080423.4) | Missense Mutation (SNP) | VAF 70/459 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as rs770879779; called by muse, mutect2, varscan2
- OR4A47 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.097); catalogued as rs750401492, COSV71445108; called by muse, mutect2
- TTC6 | c.1889A>G p.H630R | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs1026546676; called by muse, mutect2
- SPTBN2 | c.4833G>A p.M1611I | Missense Mutation (SNP) | VAF 42/433 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); called by muse, mutect2
- STAB1 | c.4055G>C p.G1352A | Missense Mutation (SNP) | VAF 70/591 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBA2 | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 25/280 reads (9%) | called by muse, mutect2
- C1QL2 | c.198C>T p.S66= | Silent (SNP) | VAF 84/825 reads (10%) | catalogued as rs1044003406; called by muse, mutect2
- RIPK4 | c.2259G>A p.T753= (on ENST00000352483; = p.T705= on NM_020639.3) | Silent (SNP) | VAF 51/572 reads (9%) | catalogued as rs754700203; called by muse, mutect2
- SPTBN2 | c.4764G>A p.L1588= | Silent (SNP) | VAF 70/597 reads (12%) | catalogued as rs750580299; called by muse, mutect2, varscan2
